Gene-level copy-number profile of tumor specimen C3N-01525-03 from CPTAC case C3N-01525, project CPTAC-3 (Uterus, NOS — Adenomas and Adenocarcinomas). Sex at birth: female; Vital status: Alive; Primary diagnosis: Endometrioid adenocarcinoma, NOS; Tissue or organ of origin: Uterus, NOS; AJCC pathologic stage: Stage I; FIGO stage: Stage I; Tumor grade: G2; Age at diagnosis: 77.3 years (28,217 days).
Specimen C3N-01525-03: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 813e0b8f-3d93-4e6e-8e22-f609aaccbb5a.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator C3N-01525-31 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,227 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: AscatNGS (2 files).
https://portal.gdc.cancer.gov/files/6eafa9e0-9392-470d-a71a-29f05ddaf7ac

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 245; copy number 2: 48,810; copy number 3: 5,584; copy number 4: 3,750; copy number 5: 7.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 7 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:230,837,119–230,869,589, 1 gene, copy number 5: C1orf198.
- chr2:219,482,073–219,538,772, 6 genes, copy number 5 (within-gene range 3–5): ASIC4-AS1, AC053503.6, SPEGNB, AC053503.4, GMPPA, ASIC4.

Autosomal genes at a single copy (total copy number 1): 209. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
